Somatic mutation profile of tumor specimen TCGA-EL-A3MY-01A (aliquot TCGA-EL-A3MY-01A-11D-A21A-08) from TCGA case TCGA-EL-A3MY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 81.3 years (29,706 days).
Specimen TCGA-EL-A3MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3e5ef3f-a67c-4867-9d87-8535dc5a571e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3MY-11A (Solid Tissue Normal), aliquot TCGA-EL-A3MY-11A-12D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d99feb97-645e-4f80-9a0a-efaa11ad0263

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGR2 | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV68597580; called by muse, mutect2, varscan2
- CACNA1A | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64202274; called by muse, mutect2, varscan2
- CD3D | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs367800432; called by muse, mutect2, varscan2
- COL4A4 | c.4369G>C p.G1457R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746683977, COSV61636900; called by muse, mutect2
- E2F3 | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV60899920; called by muse, mutect2, varscan2
- FAM120B | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as COSV53008641; called by muse, mutect2, varscan2
- HYPK | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51041490; called by muse, mutect2, varscan2
- IRX2 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.063); catalogued as COSV57409611, COSV57413864; called by muse, mutect2, varscan2
- PGBD2 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs367674534, COSV61401037, COSV61401201; called by muse, mutect2, varscan2
- PITX2 | c.729T>A p.N243K (on ENST00000354925 / NM_001204397.1; = p.N250K on NM_000325.6) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV60742372; called by muse, mutect2, varscan2
- TACC2 | c.598A>G p.M200V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57774176; called by muse, mutect2, varscan2
- TASOR2 | c.1700A>C p.D567A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.355); catalogued as COSV60169767; called by muse, mutect2, varscan2
- TTN | c.94697A>G p.Y31566C (on ENST00000591111; = p.Y24142C on NM_003319.4) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | PolyPhen benign (0.014); catalogued as COSV60364378; called by muse, mutect2
- ZNF207 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.373); catalogued as rs1225325100, COSV100340713; called by muse, mutect2
- MYO16 | c.3311_3315del p.E1104Vfs*14 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- USP9X | c.3312dup p.P1105Tfs*4 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CDH11 | c.1836C>T p.N612= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as rs1384620302, COSV51773869; called by muse, mutect2, varscan2
- PPP1R35 | c.480C>G p.L160= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV52770063, COSV99440112; called by muse, mutect2
